Somatic mutation profile of tumor specimen C3N-00295-01 (aliquot CPT0008520010) from CPTAC case C3N-00295, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 54.1 years (19,751 days).
Specimen C3N-00295-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09caff18-26f7-4c17-9aae-9f5f5c9e97a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00295-31 (Blood Derived Normal), aliquot CPT0008550002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11879296-e198-4d22-9629-7afb204c4772

The open-access MAF lists 324 somatic variants for this specimen: 220 protein-altering or splice-affecting, 72 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 191, Silent 72, Nonsense Mutation 14, Intron 14, Frame Shift Del 8, 3'UTR 5, 5'UTR 4, RNA 4, 5'Flank 4, Frame Shift Ins 3, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.1388G>A p.W463* | Nonsense Mutation (SNP) | VAF 10/210 reads (5%) | catalogued as rs863224981, CM096430; ClinVar: pathogenic; called by muse, mutect2
- EGFR | c.2155G>A p.G719S | Missense Mutation (SNP) | VAF 29/274 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28929495, COSV51766606, COSV51767289; ClinVar: pathogenic / not provided / drug response; called by muse, mutect2, varscan2
- TP53 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 44/210 reads (21%) | catalogued as rs1567541975, COSV52696505; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY10 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 21/267 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs895969024; called by muse, mutect2
- ADGRG4 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV99794671; called by muse, mutect2, varscan2
- ARL16 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as rs753824789; called by muse, mutect2, varscan2
- ATP6V0A4 | c.787G>T p.V263F | Missense Mutation (SNP) | VAF 45/399 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59474671; called by muse, mutect2, varscan2
- BBS9 | c.1930G>A p.E644K (on ENST00000242067 / NM_001348036.1; = p.E604K on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54178324; called by muse, mutect2, varscan2
- BIRC6 | c.5044G>C p.A1682P | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.398); catalogued as COSV70202725; called by muse, mutect2
- C7 | c.326G>T p.C109F | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57474007; called by muse, mutect2, varscan2
- CAMTA1 | c.2287G>T p.D763Y | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57926237; called by muse, mutect2
- CDKN2A | c.134del p.G45Vfs*8 | Frame Shift Del (DEL) | VAF 16/152 reads (11%) | catalogued as COSV58685320; called by mutect2, pindel, varscan2
- CHPF | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs762645967; called by muse, mutect2, varscan2
- CHUK | c.1358T>A p.L453* | Nonsense Mutation (SNP) | VAF 20/202 reads (10%) | catalogued as COSV64918368; called by muse, mutect2
- COL11A1 | c.2047C>A p.P683T | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100617135; called by muse, mutect2, varscan2
- COQ5 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1444150713; called by muse, mutect2
- CSMD3 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV52144331; called by muse, mutect2
- DCC | c.482G>C p.C161S | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59104224; called by muse, mutect2, varscan2
- DMD | c.3031C>A p.P1011T | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.372); catalogued as rs982781720; called by muse, mutect2
- DNAH3 | c.6221del p.G2074Vfs*59 | Frame Shift Del (DEL) | VAF 15/109 reads (14%) | catalogued as COSV54544924, COSV54553795; called by mutect2, pindel, varscan2
- EMC1 | c.955-1G>T p.X319_splice | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as rs998362250; called by muse, mutect2, varscan2
- FCRL3 | c.1372G>T p.G458W | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV63840316; called by muse, mutect2, varscan2
- FLNC | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100368615, COSV100369000; called by muse, mutect2, varscan2
- FOXG1 | c.1118C>A p.P373Q | Missense Mutation (SNP) | VAF 50/700 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV57397080, COSV57397858; called by muse, mutect2
- GP6 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.305); catalogued as rs751979972, COSV100117513; called by muse, mutect2
- GPATCH8 | c.1207A>C p.K403Q | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV100132755; called by muse, mutect2, varscan2
- GUCY1A1 | c.869T>C p.F290S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV56656472; called by muse, mutect2, varscan2
- GYS2 | c.215A>G p.H72R | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.158); catalogued as rs574787003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1674C>G p.I558M | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV61179626; called by muse, mutect2
- IQSEC3 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 62/374 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.86); catalogued as rs1555065986; called by muse, mutect2, varscan2
- LILRB5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs923890744, COSV60259321; called by muse, mutect2, varscan2
- LMBRD1 | c.223A>T p.K75* | Nonsense Mutation (SNP) | VAF 11/190 reads (6%) | catalogued as COSV100992396; called by muse, mutect2
- LRP6 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs149633733; called by muse, mutect2, varscan2
- LRRK2 | c.5317G>T p.G1773C | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100109757; called by muse, mutect2, varscan2
- MC4R | c.472C>A p.H158N | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55352123; called by muse, mutect2
- METTL17 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.01); catalogued as rs752124334, COSV100228414; called by muse, mutect2, varscan2
- MMEL1 | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56522296; called by muse, mutect2, varscan2
- MRPL14 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752775868, COSV64394549, COSV64394736; called by muse, varscan2
- MTMR2 | c.1667A>G p.Y556C | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs147170889; called by muse, mutect2, varscan2
- MUC17 | c.9373C>T p.L3125F | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs1278601389, COSV100075597; called by muse, mutect2, varscan2
- MYLK4 | c.418A>G p.R140G | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as rs1346107824; called by muse, mutect2
- NAALAD2 | c.1099C>A p.H367N | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58959705, COSV58961265; called by muse, mutect2
- NLRP4 | c.1105A>C p.T369P | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1183049946; called by muse, mutect2, varscan2
- NOTCH3 | c.4302del p.W1434Cfs*144 | Frame Shift Del (DEL) | VAF 62/289 reads (21%) | catalogued as COSV54625713; called by mutect2, pindel, varscan2
- OBSCN | c.17020del p.A5674Pfs*21 | Frame Shift Del (DEL) | VAF 10/112 reads (9%) | catalogued as rs757737800; called by mutect2, pindel
- OR2J2 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs750646669, COSV65847858, COSV65848137; called by muse, mutect2
- OR2M2 | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV62898353, COSV62898618; called by muse, mutect2
- OR56A1 | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV100360529, COSV57364136; called by muse, mutect2, varscan2
- OR5AP2 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs745826090; called by muse, mutect2, varscan2
- OR7D4 | c.680del p.G227Efs*34 | Frame Shift Del (DEL) | VAF 26/276 reads (9%) | catalogued as COSV100432616; called by mutect2, pindel
- OSBPL8 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1386010557; called by muse, mutect2
- PABPC5 | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57041695; called by muse, mutect2
- PCDH17 | c.173G>C p.R58P | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.142); catalogued as COSV100931974, COSV64979882; called by muse, mutect2
- PCDHGA5 | c.571T>G p.Y191D | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV99548636; called by muse, mutect2
- POSTN | c.1260G>A p.M420I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.81); catalogued as rs866803726; called by muse, mutect2
- PRDM7 | c.731C>A p.P244Q | Missense Mutation (SNP) | VAF 51/466 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as COSV57986277; called by muse, mutect2, varscan2
- RERGL | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.824); catalogued as rs1052380827; called by muse, mutect2, varscan2
- RFXAP | c.219C>A p.Y73* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as CM122029; called by muse, mutect2
- RSPO3 | c.155A>G p.N52S | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV63153840; called by muse, mutect2, varscan2
- SALL1 | c.1206C>G p.F402L | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as CD991867; called by muse, mutect2
- SEC14L5 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV52040376; called by muse, mutect2
- SFMBT2 | c.1205C>T p.T402I | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs200930460; called by muse, mutect2, varscan2
- SH3BGRL | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs756070302, COSV100943387; called by muse, mutect2
- SIPA1L3 | c.2579G>T p.R860L | Missense Mutation (SNP) | VAF 123/297 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV55915469, COSV99730070; called by muse, mutect2, varscan2
- SLC26A5 | c.2165A>T p.Q722L | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59700867; called by muse, mutect2, varscan2
- SLC35F6 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60426305; called by muse, mutect2
- SLC7A1 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101060301; called by muse, mutect2
- SLITRK2 | c.2311C>A p.L771I | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV59425715; called by muse, mutect2
- SORCS1 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190321453, COSV53868602, COSV53902225, COSV99549152; called by muse, mutect2
- SPACA1 | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.519); catalogued as COSV52758916, COSV52759748; called by muse, mutect2, varscan2
- SRPK3 | c.1288C>G p.R430G | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54206752; called by muse, mutect2, varscan2
- SSC5D | c.3936C>A p.Y1312* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as COSV67476490; called by muse, mutect2, varscan2
- SYNJ1 | c.9G>C p.K3N | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1250657533, COSV59144673; called by muse, mutect2
- TBX5 | c.793C>G p.Q265E | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV59865952; called by muse, mutect2, varscan2
- TENM1 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs148771973, COSV64436007; called by muse, mutect2
- TEX45 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as rs1168056010; called by muse, mutect2
- THAP11 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.02); catalogued as COSV54646404; called by muse, mutect2, varscan2
- TRIM14 | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52964040; called by muse, mutect2, varscan2
- UFL1 | c.2286A>T p.E762D | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1562258248; called by muse, mutect2
- USP17L4 | c.1046T>C p.M349T | Missense Mutation (SNP) | VAF 24/588 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1278891953; called by muse, mutect2
- USP31 | c.2854G>T p.E952* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as COSV54851373; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 17/122 reads (14%) | catalogued as rs764735138; called by mutect2, varscan2
- ZNF468 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs578209496; called by muse, mutect2
- ZNF521 | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100832813; called by muse, mutect2
- ZNF611 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV60540784; called by muse, mutect2
- ZNF670 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 55/315 reads (17%) | catalogued as rs1308586093, COSV63607568; called by muse, mutect2, varscan2
- ZNF727 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs375815259, COSV101407016; called by muse, mutect2, varscan2
- ACSM1 | c.137C>G p.P46R | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- ADCY2 | c.1525C>G p.H509D | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.021); called by muse, mutect2
- ADGRV1 | c.7616T>A p.L2539Q | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.707); called by muse, mutect2
- AGA | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- AGBL4 | c.233G>C p.R78P | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- AKAP9 | c.192A>T p.E64D | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- AKAP9 | c.3542G>T p.G1181V | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- ANKRD11 | c.2918G>T p.R973L | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ANO4 | c.508del p.E170Kfs*10 (on ENST00000392977 / NM_001286615.2; = p.E135Kfs*10 on NM_178826.4) | Frame Shift Del (DEL) | VAF 20/134 reads (15%) | called by mutect2, pindel, varscan2
- ARHGAP28 | c.1901G>T p.R634L (on ENST00000383472 / NM_001366230.1; = p.R475L on NM_001010000.3) | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- ARHGAP36 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2
- ARID1A | c.3868A>G p.T1290A | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASIC5 | c.411A>C p.K137N | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- B4GALT1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 22/305 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- BRWD3 | c.3814G>A p.E1272K | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, mutect2
- CAMK2D | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC141 | c.1277C>A p.S426Y | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2
- CCDC8 | c.1345C>A p.P449T | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); called by muse, mutect2
- CDH2 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDK3 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP170B | c.3583A>T p.S1195C (on ENST00000453495; = p.S1124C on NM_015005.3) | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- CFLAR | c.1180A>G p.T394A | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CHST5 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.049); called by muse, mutect2
- CNTN6 | c.308C>A p.T103N | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, varscan2
- COL19A1 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- CRACD | c.3408C>A p.S1136R | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); called by muse, varscan2
- CRB1 | c.1217G>T p.C406F | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.1202T>A p.L401H | Missense Mutation (SNP) | VAF 25/275 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2
- CTDSPL | c.818_*1del | Nonstop Mutation (DEL) | VAF 17/110 reads (15%) | called by mutect2, pindel, varscan2
- CUL4B | c.1853G>T p.G618V | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CUL9 | c.7026_7027insTGT p.A2342_R2343insC | In Frame Ins (INS) | VAF 12/123 reads (10%) | called by mutect2, pindel
- DCDC1 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DHRS7C | c.497T>C p.M166T (on ENST00000330255 / NM_001220493.2; = p.M165T on NM_001105571.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2
- DNAJC5G | c.49A>T p.S17C | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- DST | c.2617dup p.T873Nfs*11 (on ENST00000361203 / NM_001374722.1; = p.T547Nfs*11 on NM_001723.6) | Frame Shift Ins (INS) | VAF 15/195 reads (8%) | called by mutect2, pindel
- DUXB | c.333G>C p.W111C | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.3); called by muse, mutect2
- EDA | c.346T>A p.L116M | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.36); called by muse, mutect2
- EPB41L3 | c.*7G>T | Splice Region (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- ERICH3 | c.4263G>A p.M1421I | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2
- FBN2 | c.3190G>T p.V1064F | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FBN3 | c.265_266del p.A89Lfs*3 | Frame Shift Del (DEL) | VAF 16/131 reads (12%) | called by pindel, varscan2
- GGH | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GLI2 | c.4085C>T p.P1362L (on ENST00000361492 / NM_001374353.1; = p.P1379L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- GPC4 | c.1617C>A p.Y539* | Nonsense Mutation (SNP) | VAF 15/215 reads (7%) | called by muse, mutect2
- GRIN2A | c.2153T>A p.V718D | Missense Mutation (SNP) | VAF 35/312 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- GRM8 | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.217); called by muse, mutect2
- HCN4 | c.1490T>G p.L497R | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCN4 | c.1489C>G p.L497V | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HECW1 | c.442A>T p.S148C | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- HEPH | c.302C>A p.P101Q (on ENST00000343002; = p.P155Q on NM_138737.5) | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HHIPL2 | c.561C>G p.N187K | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- HIF3A | c.117C>A p.H39Q (on ENST00000377670 / NM_152795.4; = p.T19K on NM_022462.4) | Missense Mutation (SNP) | VAF 29/326 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.96); called by muse, mutect2
- HSPA1L | c.1327C>G p.Q443E | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGKV1D-43 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IGSF9B | c.2731C>T p.Q911* | Nonsense Mutation (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- IL13RA1 | c.546C>A p.Y182* | Nonsense Mutation (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- KCNA4 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- KCNB2 | c.2050C>A p.Q684K | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF2B | c.1169A>T p.Q390L | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KLHL2 | c.1262A>G p.N421S | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- KRTAP5-9 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2
- LACRT | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.136); called by muse, mutect2
- LAMA5 | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LILRA2 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2
- LRRC31 | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2
- MACF1 | c.9496C>G p.Q3166E | Missense Mutation (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- MAGEC3 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MAP3K1 | c.164C>A p.A55E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- MC4R | c.473A>T p.H158L | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- MERTK | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MGST3 | c.337A>T p.S113C | Missense Mutation (SNP) | VAF 39/363 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MINAR2 | c.137A>T p.Q46L | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- MIOS | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- MISP3 | c.138dup p.K47Qfs*37 | Frame Shift Ins (INS) | VAF 43/322 reads (13%) | called by mutect2, pindel, varscan2
- MLH3 | c.171T>G p.N57K | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOB1A | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH5 | c.2935C>A p.P979T | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.779); called by muse, mutect2
- MS4A4A | c.444C>G p.I148M | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.401); called by muse, mutect2
- MSANTD2 | c.815C>A p.S272Y (on ENST00000374979 / NM_001308027.2; = p.S220Y on NM_024631.4) | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.556); called by muse, mutect2
- MUTYH | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 32/516 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- MYCBP2 | c.68G>A p.R23Q (on ENST00000357337; = p.R61Q on NM_015057.5) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH4 | c.2590A>G p.K864E | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2
- MYH7 | c.5174A>T p.N1725I | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); called by muse, mutect2
- MYLK | c.2758G>C p.A920P | Missense Mutation (SNP) | VAF 44/674 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2
- MYO15A | c.2600G>T p.R867L | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); called by muse, mutect2
- NF2 | c.527T>C p.L176P | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2
- NRCAM | c.2005C>T p.P669S (on ENST00000379028 / NM_001371124.1; = p.P653S on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OPRM1 | c.949A>T p.T317S | Missense Mutation (SNP) | VAF 43/306 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- OR10G4 | c.607G>C p.G203R | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2G3 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4K14 | c.393G>T p.L131F | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR6C4 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- P2RY8 | c.476C>A p.A159E | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2
- PAPOLB | c.596T>A p.I199K | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PAXIP1 | c.3001A>G p.K1001E | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.145); called by muse, mutect2
- PCDH17 | c.2968G>T p.V990L | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.076); called by muse, mutect2
- PCDHGA1 | c.1955C>A p.P652H | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCNT | c.4461G>T p.E1487D | Missense Mutation (SNP) | VAF 31/313 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PDE7B | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDHA2 | c.130T>A p.L44M | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEKHG3 | c.2615A>C p.Q872P (on ENST00000394691; = p.Q928P on NM_001308147.2) | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PON1 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- PRG4 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- PRUNE2 | c.1997dup p.N666Kfs*10 | Frame Shift Ins (INS) | VAF 16/122 reads (13%) | called by mutect2, pindel, varscan2
- PSMD2 | c.775T>C p.F259L | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); called by muse, mutect2
- PTGFR | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PWWP3B | c.1906A>T p.I636F | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- RABEP1 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- RAPGEF3 | c.1560G>T p.L520F (on ENST00000389212; = p.L478F on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.186); called by muse, mutect2
- RBM6 | c.1200T>A p.D400E | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- RNF38 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- RP1 | c.6134G>C p.G2045A | Missense Mutation (SNP) | VAF 35/423 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2
- SHISA6 | c.1025C>T p.P342L (on ENST00000409168 / NM_001173461.1; = p.P393L on NM_207386.4) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SLC17A6 | c.1661G>T p.W554L | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- SMYD1 | c.1283G>T p.G428V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SNX18 | c.1318G>T p.D440Y | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SP140 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 12/187 reads (6%) | called by muse, mutect2
- SYNE1 | c.25697T>G p.L8566R (on ENST00000367255 / NM_182961.4; = p.L8518R on NM_033071.3) | Missense Mutation (SNP) | VAF 24/269 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYT10 | c.109A>T p.I37F | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF1L | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2
- TEX13C | c.2294C>G p.P765R | Missense Mutation (SNP) | VAF 41/362 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- THSD7A | c.772G>T p.G258W | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMEM132C | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRBJ2-2P | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- UBP1 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 13/225 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UNC13A | c.3760A>C p.I1254L | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2
- WDR5B | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2
- XIAP | c.969G>C p.W323C | Missense Mutation (SNP) | VAF 9/278 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- XIRP2 | c.9088G>T p.V3030F (on ENST00000628543; = p.V3205F on NM_152381.6) | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- XKR4 | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.334); called by muse, mutect2
- ZAP70 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF557 | c.1005T>A p.H335Q (on ENST00000414706 / NM_001044388.2; = p.H342Q on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZSWIM8 | c.5081C>G p.P1694R (on ENST00000605216 / NM_001242487.2; = p.P1699R on NM_015037.3) | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP4M1 | c.1149A>T p.P383= | Silent (SNP) | VAF 28/262 reads (11%) | called by muse, mutect2, varscan2
- ATAD1 | c.591T>C p.F197= | Silent (SNP) | VAF 18/129 reads (14%) | called by muse, mutect2, varscan2
- BRCA1 | c.5430G>A p.V1810= | Silent (SNP) | VAF 37/351 reads (11%) | catalogued as rs786201582; ClinVar: likely benign; called by muse, mutect2, varscan2
- CAMK2D | c.1167G>T p.V389= | Silent (SNP) | VAF 14/181 reads (8%) | called by muse, mutect2
- CD93 | c.1035C>T p.D345= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs368417861; called by mutect2, varscan2
- CDH7 | c.396C>G p.P132= | Silent (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- CFHR4 | c.855G>T p.T285= (on ENST00000367416 / NM_001201551.2; = p.T286= on NM_001201550.3) | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV99260348; called by muse, varscan2
- CPLX4 | c.375G>A p.G125= | Silent (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- CSMD3 | c.7206C>A p.P2402= (on ENST00000297405 / NM_001363185.1; = p.P2298= on NM_052900.3) | Silent (SNP) | VAF 14/281 reads (5%) | catalogued as rs1455896733; called by muse, mutect2
- CSMD3 | c.1203C>A p.L401= | Silent (SNP) | VAF 24/272 reads (9%) | catalogued as COSV52186262; called by muse, mutect2
- DDX60 | c.1665G>T p.V555= | Silent (SNP) | VAF 23/216 reads (11%) | catalogued as COSV67098205; called by muse, mutect2, varscan2
- DMD | c.7485A>T p.S2495= | Silent (SNP) | VAF 20/266 reads (8%) | called by muse, mutect2
- DPY19L2 | c.240C>A p.G80= | Silent (SNP) | VAF 34/247 reads (14%) | called by muse, mutect2, varscan2
- EEF1AKNMT | c.414G>A p.Q138= (on ENST00000361735 / NM_015935.5; = p.Q52= on NM_014955.3) | Silent (SNP) | VAF 12/246 reads (5%) | called by muse, mutect2
- EGFLAM | c.274C>A p.R92= | Silent (SNP) | VAF 19/177 reads (11%) | catalogued as rs764687373; called by muse, mutect2, varscan2
- EIF2AK3 | c.21G>T p.P7= | Silent (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
- FFAR4 | c.156A>T p.A52= | Silent (SNP) | VAF 17/254 reads (7%) | called by muse, mutect2
- FRY | c.3348G>A p.Q1116= | Silent (SNP) | VAF 15/187 reads (8%) | catalogued as COSV66583464; called by muse, mutect2
- GABRE | c.495G>A p.E165= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as rs763376461; called by muse, mutect2
- GPR141 | c.759G>T p.T253= | Silent (SNP) | VAF 23/149 reads (15%) | catalogued as rs142585981; called by muse, mutect2, varscan2
- H3C7 | c.192C>T p.R64= | Silent (SNP) | VAF 16/360 reads (4%) | called by muse, mutect2
- HCRTR2 | c.768T>A p.P256= | Silent (SNP) | VAF 16/231 reads (7%) | called by muse, mutect2
- HERC2 | c.3510G>A p.R1170= | Silent (SNP) | VAF 36/305 reads (12%) | called by muse, mutect2, varscan2
- IGKV2D-24 | c.33A>T p.L11= | Silent (SNP) | VAF 18/177 reads (10%) | called by muse, mutect2, varscan2
- IGKV3D-11 | c.123C>A p.L41= | Silent (SNP) | VAF 25/360 reads (7%) | called by muse, mutect2
- IMP3 | c.186G>C p.L62= | Silent (SNP) | VAF 30/149 reads (20%) | called by muse, mutect2, varscan2
- IMPG2 | c.3486G>T p.V1162= | Silent (SNP) | VAF 40/214 reads (19%) | called by muse, mutect2, varscan2
- ITPRIPL2 | c.561G>T p.A187= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs781314842, COSV101198176; called by muse, mutect2, varscan2
- KCNA6 | c.1206C>T p.D402= | Silent (SNP) | VAF 40/345 reads (12%) | catalogued as rs762158886, COSV54975964; called by muse, mutect2, varscan2
- KCNJ11 | c.150G>T p.R50= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV100217586; called by muse, mutect2
- KIT | c.249C>A p.I83= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as COSV99852606; called by muse, mutect2
- LEF1 | c.1131G>A p.K377= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- LUZP4 | c.783C>T p.A261= | Silent (SNP) | VAF 21/394 reads (5%) | called by muse, mutect2
- MAGEC1 | c.2541T>G p.P847= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- MFSD10 | c.294C>T p.V98= | Silent (SNP) | VAF 9/143 reads (6%) | catalogued as rs1353281448; called by muse, mutect2
- NAT10 | c.159T>C p.P53= | Silent (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2, varscan2
- NPAS3 | c.816C>G p.T272= (on ENST00000356141 / NM_001164749.2; = p.T240= on NM_022123.3) | Silent (SNP) | VAF 20/157 reads (13%) | catalogued as rs774886036; called by muse, mutect2, varscan2
- NRK | c.4425C>A p.T1475= | Silent (SNP) | VAF 11/186 reads (6%) | called by muse, mutect2
- NUP93 | c.780G>A p.A260= | Silent (SNP) | VAF 6/101 reads (6%) | catalogued as rs1223754880, COSV57428227; called by muse, mutect2
- OR56A5 | c.558T>C p.S186= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as rs1288170264; called by muse, mutect2, varscan2
- OR5M10 | c.273C>A p.T91= | Silent (SNP) | VAF 24/261 reads (9%) | called by muse, mutect2
- OR9Q2 | c.75T>A p.V25= | Silent (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- ORAI2 | c.666G>T p.L222= | Silent (SNP) | VAF 12/129 reads (9%) | called by muse, mutect2
- PCDHB4 | c.2232G>T p.L744= | Silent (SNP) | VAF 21/272 reads (8%) | catalogued as rs4143454; called by muse, mutect2
- PDE8B | c.1326G>T p.A442= | Silent (SNP) | VAF 26/350 reads (7%) | catalogued as COSV53740143; called by muse, mutect2
- PIP4K2B | c.642G>A p.K214= | Silent (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- PIP5K1A | c.735C>T p.N245= (on ENST00000368888 / NM_001135638.2; = p.N232= on NM_003557.3) | Silent (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- PLK4 | c.303A>G p.L101= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs893628118, COSV99584476; called by muse, mutect2
- QSOX2 | c.1104G>C p.P368= | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as rs151337392; called by muse, mutect2, varscan2
- RAG1 | c.1722A>G p.E574= | Silent (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- REM1 | c.753G>C p.A251= | Silent (SNP) | VAF 25/227 reads (11%) | called by muse, mutect2, varscan2
- RIMS1 | c.4959C>A p.I1653= | Silent (SNP) | VAF 36/275 reads (13%) | called by muse, mutect2, varscan2
- RYR1 | c.8937T>A p.A2979= | Silent (SNP) | VAF 15/473 reads (3%) | called by muse, mutect2
- SBK3 | c.27T>A p.P9= | Silent (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2
- SLC13A3 | c.1476G>T p.L492= | Silent (SNP) | VAF 19/182 reads (10%) | called by muse, mutect2, varscan2
- SLC44A1 | c.459A>T p.P153= | Silent (SNP) | VAF 27/168 reads (16%) | called by muse, varscan2
- SPIRE1 | c.828G>A p.V276= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- SSTR3 | c.747G>A p.R249= | Silent (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- TADA2A | c.1305C>T p.I435= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- THEM6 | c.397C>T p.L133= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs782416230; called by muse, mutect2, varscan2
- TNIK | c.1272C>A p.R424= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV99460853; called by muse, varscan2
- TRIM49C | c.1143G>T p.G381= | Silent (SNP) | VAF 35/517 reads (7%) | called by muse, mutect2
- UNC80 | c.6870G>T p.G2290= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as rs1320810103; called by muse, varscan2
- UTF1 | c.906C>A p.T302= | Silent (SNP) | VAF 12/131 reads (9%) | called by muse, mutect2
- VIM | c.672G>T p.V224= | Silent (SNP) | VAF 18/364 reads (5%) | catalogued as rs1236184497; called by muse, mutect2
- VSIG2 | c.933G>T p.S311= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV99423552; called by muse, mutect2, varscan2
- VSTM1 | c.96C>T p.H32= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs746329632; called by muse, mutect2
- WDR64 | c.585G>T p.G195= | Silent (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- ZCCHC12 | c.588C>A p.L196= | Silent (SNP) | VAF 31/361 reads (9%) | called by muse, mutect2
- ZIC1 | c.231G>T p.L77= | Silent (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- ZMYM3 | c.2265G>A p.Q755= | Silent (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2
- ZNF781 | c.670C>T p.L224= | Silent (SNP) | VAF 67/196 reads (34%) | catalogued as COSV62202670; called by muse, mutect2, varscan2
- ATP11B | c.-96G>T | 5'UTR (SNP) | VAF 8/53 reads (15%) | catalogued as rs1258313478; called by muse, mutect2
- CBLL1 | chr7:107744080 G>C | 5'Flank (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2
- CFL2 | c.4-88G>T | Intron (SNP) | VAF 24/286 reads (8%) | called by muse, mutect2
- DCAF17 | c.*3651G>A | 3'UTR (SNP) | VAF 18/322 reads (6%) | called by muse, mutect2
- ERBB4 | c.234+11G>T | Intron (SNP) | VAF 17/198 reads (9%) | called by muse, mutect2
- GPATCH8 | c.*1563A>G | 3'UTR (SNP) | VAF 33/187 reads (18%) | called by muse, mutect2, varscan2
- HHLA1 | chr8:132105271 T>G | 5'Flank (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- IGF1R | c.2201+16G>T | Intron (SNP) | VAF 29/243 reads (12%) | called by muse, mutect2, varscan2
- LINC02054 | n.2489G>A | RNA (SNP) | VAF 33/218 reads (15%) | catalogued as rs1010490875; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640935 A>T | 3'Flank (SNP) | VAF 10/252 reads (4%) | called by muse, mutect2
- MFRP | chr11:119345920 C>G | 5'Flank (SNP) | VAF 15/132 reads (11%) | catalogued as rs926472743; called by muse, mutect2, varscan2
- MINPP1 | c.-9G>A | 5'UTR (SNP) | VAF 12/217 reads (6%) | catalogued as rs1369068106; called by muse, mutect2
- MIR888 | n.59T>A | RNA (SNP) | VAF 13/81 reads (16%) | called by muse, varscan2
- MS4A6A | c.282+77C>T | Intron (SNP) | VAF 19/162 reads (12%) | catalogued as rs1394960079; called by muse, mutect2, varscan2
- MSX1 | c.470-95C>A | Intron (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- NBPF22P | n.1071G>T | RNA (SNP) | VAF 29/426 reads (7%) | called by muse, mutect2
- OR7E5P | n.252C>A | RNA (SNP) | VAF 14/278 reads (5%) | called by muse, mutect2
- PCGF2 | chr17:38749621 G>A | 5'Flank (SNP) | VAF 7/110 reads (6%) | catalogued as rs1055458644; called by muse, mutect2
- PRKAG2 | c.115-20425A>T | Intron (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- PRPF31 | c.238+18G>A | Intron (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- RNF34 | c.-1C>A | 5'UTR (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- RSRC1 | c.320+8175G>C | Intron (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- SAMD4A | c.197-16209G>T | Intron (SNP) | VAF 13/176 reads (7%) | called by muse, mutect2
- SDHAF2 | c.*30C>G | 3'UTR (SNP) | VAF 28/303 reads (9%) | called by muse, mutect2
- SLA | c.-12A>G | 5'UTR (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- SLC10A7 | c.435+68G>C | Intron (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- TP53 | c.993+205A>T | Intron (SNP) | VAF 19/212 reads (9%) | called by muse, mutect2
- TTC23 | c.1144-292_1144-287del | Intron (DEL) | VAF 10/128 reads (8%) | called by mutect2, pindel
- UBE2F | c.119-1744G>T | Intron (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- UMPS | c.*2464G>A | 3'UTR (SNP) | VAF 82/442 reads (19%) | catalogued as rs1188749983; called by muse, mutect2, varscan2
- WNK4 | c.792-103G>T | Intron (SNP) | VAF 7/59 reads (12%) | catalogued as COSV53822181; called by muse, mutect2, varscan2
- XIRP2 | c.*1307G>C | 3'UTR (SNP) | VAF 7/130 reads (5%) | catalogued as COSV54685362; called by muse, mutect2
